CPTAC case SC-0547 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b89ea55-ba0c-4d54-a4cf-fa9971867da6

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 55.0 years (20,089 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N3c; Progression or recurrence: yes; Days to recurrence: 30 days; Days to last follow up: 883 days (2.4 years); Clark level: V.
   Pathology details: Breslow thickness: 8.9.

Biospecimens (1 sample)
- Sample S-2108-019469: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 298 mg; Method of sample procurement: Tumor Resection.
